Somatic mutation profile of tumor specimen TCGA-CZ-5461-01A (aliquot TCGA-CZ-5461-01A-01D-1501-10) from TCGA case TCGA-CZ-5461, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 52.1 years (19,030 days).
Specimen TCGA-CZ-5461-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ca1607c-dbea-4fe1-bc99-fae41293438d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5461-11A (Solid Tissue Normal), aliquot TCGA-CZ-5461-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4796af7f-2f8e-4ea1-a505-e8bdcdd4158a

The open-access MAF lists 61 somatic variants for this specimen: 53 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 42, Silent 8, Frame Shift Del 4, Nonsense Mutation 4, Splice Site 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.4873C>T p.R1625C | Missense Mutation (SNP) | VAF 168/355 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57429702; called by muse, mutect2, varscan2
- ACSM5 | c.1570T>C p.Y524H | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59373147; called by muse, mutect2, varscan2
- C8orf37 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 95/451 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as COSV54412921; called by muse, mutect2, varscan2
- CCNB3 | c.2642G>T p.W881L | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV52076203; called by muse, mutect2, varscan2
- CDH16 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV55338103; called by muse, mutect2, varscan2
- CDON | c.218A>T p.E73V | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as COSV54999994; called by muse, mutect2, varscan2
- CELSR2 | c.2101A>T p.N701Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54775698; called by muse, mutect2, varscan2
- DLG2 | c.1397A>T p.Q466L | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV54663910; called by muse, mutect2, varscan2
- DYNC1H1 | c.2134G>A p.G712S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs748062639, COSV100795245, COSV64139195; called by muse, mutect2, varscan2
- EDIL3 | c.553G>T p.G185* | Nonsense Mutation (SNP) | VAF 154/493 reads (31%) | catalogued as COSV56897132, COSV56908142; called by muse, mutect2, varscan2
- EFCAB5 | c.4339G>C p.V1447L | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs1244550673, COSV57931863; called by muse, mutect2
- GCFC2 | c.2105T>C p.V702A | Missense Mutation (SNP) | VAF 127/393 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV58082091; called by muse, mutect2, varscan2
- HDAC7 | c.1856G>C p.G619A (on ENST00000427332; = p.G658A on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV50388727; called by muse, mutect2, varscan2
- KLK13 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs150383488; called by muse, mutect2, varscan2
- LIG4 | c.2554G>A p.V852I | Missense Mutation (SNP) | VAF 149/445 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV63597502; called by muse, mutect2, varscan2
- LXN | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.695); catalogued as COSV51834074; called by muse, mutect2
- MACF1 | c.16414A>T p.T5472S (on ENST00000372915; = p.T3405S on NM_012090.5) | Missense Mutation (SNP) | VAF 51/141 reads (36%) | catalogued as COSV57131563; called by muse, mutect2, varscan2
- MEGF10 | c.2221T>C p.Y741H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.168); catalogued as rs907242213, COSV57252809; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRPS18C | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 159/616 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.883); catalogued as rs766854181, COSV55026252; called by muse, mutect2, varscan2
- NBR1 | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.959); catalogued as rs1430986515, COSV57833917; called by muse, mutect2, varscan2
- NCOR1 | c.5544G>T p.R1848S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs781525832, COSV51984344; called by muse, mutect2, varscan2
- NPR1 | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64117832; called by muse, mutect2, varscan2
- NTRK3 | c.2204G>A p.R735H (on ENST00000360948 / NM_001012338.2; = p.R721H on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62297428; called by muse, mutect2, varscan2
- PAXBP1 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 290/972 reads (30%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.95); catalogued as rs1364042694, COSV51610523; called by muse, mutect2, varscan2
- PBRM1 | c.139-2A>G p.X47_splice | Splice Site (SNP) | VAF 57/118 reads (48%) | catalogued as COSV56264479; called by muse, varscan2
- PGPEP1L | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs1288712904, COSV51284433; called by muse, mutect2, varscan2
- PHF6 | c.875G>C p.C292S | Missense Mutation (SNP) | VAF 24/297 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59704564; called by muse, mutect2
- PHLDB1 | c.54G>T p.M18I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV61880307; called by muse, mutect2, varscan2
- PIWIL1 | c.2079G>A p.M693I | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV55349028; called by muse, mutect2, varscan2
- PLPPR1 | c.377G>T p.R126I | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV66455158; called by muse, mutect2, varscan2
- PMFBP1 | c.2578G>T p.E860* (on ENST00000537465; = p.E855* on NM_031293.3) | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV52827643; called by muse, mutect2, varscan2
- RAB18 | c.391G>C p.V131L | Missense Mutation (SNP) | VAF 216/605 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV63613795; called by muse, mutect2, varscan2
- RPS4Y1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as COSV51711160; called by muse, mutect2
- RYR1 | c.11613G>C p.E3871D | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV62103147; called by muse, mutect2, varscan2
- SDR16C5 | c.280G>C p.A94P | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV58127271, COSV58128559; called by muse, mutect2, varscan2
- SGPL1 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV64591936; called by muse, mutect2, varscan2
- SUV39H2 | c.989A>G p.N330S (on ENST00000354919 / NM_001193424.2; = p.N270S on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57954696; called by muse, mutect2, varscan2
- SYNE1 | c.19661A>G p.Q6554R (on ENST00000367255 / NM_182961.4; = p.Q6483R on NM_033071.3) | Missense Mutation (SNP) | VAF 84/257 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV55033957; called by muse, mutect2
- TAS2R8 | c.531A>G p.I177M | Missense Mutation (SNP) | VAF 262/700 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as COSV53689798; called by muse, varscan2
- TMOD2 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as rs1054663925, COSV51042776; called by muse, mutect2, varscan2
- TP53INP1 | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV61332211; called by muse, mutect2, varscan2
- TRIM50 | c.728A>T p.K243M | Missense Mutation (SNP) | VAF 120/390 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV60794456; called by muse, mutect2, varscan2
- TTK | c.1769A>C p.D590A | Missense Mutation (SNP) | VAF 118/312 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV57885103; called by muse, mutect2, varscan2
- VWCE | c.1203G>C p.E401D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV57113660; called by muse, mutect2
- WASHC2A | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 112/472 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs782633271, COSV50954414; called by muse, mutect2, varscan2
- WFDC1 | c.79C>A p.H27N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54744902; called by muse, varscan2
- CHL1 | c.2084G>A p.S695N (on ENST00000397491 / NM_001253387.1; = p.S711N on NM_006614.4) | Missense Mutation (SNP) | VAF 3/58 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2
- CNOT9 | c.221_223delinsTT p.Y74Ffs*9 | Frame Shift Del (DEL) | VAF 83/358 reads (23%) | called by pindel, varscan2*
- FBXO43 | c.1869dup p.Y624Ifs*3 | Frame Shift Ins (INS) | VAF 34/115 reads (30%) | called by mutect2, pindel, varscan2
- IGHG4 | c.471del p.W157Cfs*38 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- IKZF4 | c.1136del p.E379Gfs*64 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- MYO19 | c.2054_2069del p.S685Kfs*29 (on ENST00000614623 / NM_001163735.1; = p.S485Kfs*29 on NM_025109.5) | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | called by mutect2, pindel, varscan2
- ZNF141 | c.196A>T p.K66* | Nonsense Mutation (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- AIDA | c.324C>T p.F108= | Silent (SNP) | VAF 18/260 reads (7%) | catalogued as COSV60664800; called by muse, mutect2
- ATP6V0A1 | c.996C>T p.S332= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV52873102; called by muse, mutect2, varscan2
- CSNK1A1L | c.294A>G p.E98= | Silent (SNP) | VAF 74/264 reads (28%) | catalogued as COSV65789930; called by muse, varscan2
- GGNBP2 | c.897G>T p.L299= | Silent (SNP) | VAF 62/247 reads (25%) | called by muse, mutect2, varscan2
- OTOF | c.852G>A p.K284= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV55509591; called by muse, mutect2
- SLTM | c.1617G>T p.S539= | Silent (SNP) | VAF 36/803 reads (4%) | catalogued as rs1233752950, COSV51053447, COSV51055691; called by muse, mutect2
- TG | c.7383C>A p.V2461= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV55084819; called by muse, mutect2
- ZFP14 | c.576A>G p.R192= | Silent (SNP) | VAF 61/161 reads (38%) | catalogued as COSV54203474; called by muse, mutect2, varscan2
